Surgical pathology report (de-identified scan), TCGA case TCGA-ZQ-A9CR, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Tayside Tissue Bank, specimen TCGA-ZQ-A9CR-01A (Primary Tumor).

[page 1 of 4]
ICD 8-3
Adenocarcinoma, tubular 8211/3
Adenocarcinoma, intestinal type 8144/3
Site: Gastric antrum 016.3
20 01/19/14

Nature of Specimen(s)

Stomach.

Clinical Information Supplied

Subtotal gastrectomy. Obstructing antral gastric cancer.
Clinically T3.

Macro Report

The specimen comprises a partial gastrectomy with attached section of omentum. The stomach measures 140mm (greater curve) x 180mm (lesser curve) x 110mm in width. The greater omentum measures 290 x 160mm and the lesser omentum measures 60 x 50mm. The proximal duodenum measures 25mm. No obvious oesophageal tissue is present. The specimen has been partially opened to allow for fixation. On sectioning an infiltrating tumour mass is seen to arise from the posterior antral wall. The tumour measures approximately 70mm in maximum dimension and appears to be 15mm from the nearest (distal) margin. The tumour obstructs the gastric antrum. The tumour is 90mm from the proximal margin. Macroscopically the tumour does appear to extend into the surrounding fat posteriorly and appears to have breached the muscularis. There are several obviously macroscopically involved lymph nodes.

Blocks taken as: A&B - proximal margin, C&D - distal margin, E-I - sections through tumour, J - cruciate block showing tumour and relationship to distal margin, K-R - one lymph node per cassette, S-W - two lymph nodes per cassette, X - three lymph nodes on one cassette, Y - section of normal gastric mucosa. Tissue remains.

Macro Report

Type of specimen: Subtotal gastrectomy

Length of specimen - lesser curve (mm):	180mm
Length of specimen - greater curve (mm):	140mm
Length of duodenum (mm):	25mm
Length of oesophagus (mm):	N/A

Page 1 of 3

ACKNOWLEDGEMENT OF RECEIPT	
WARD SECRETARY	DOCTOR

FEMALE

PROUREMENT DATE:

[page 2 of 4]
Site of tumour: Antrum

Macroscopic type: Diffusely infiltrating

Size of tumour (mm) - 77mm in maximum dimension

Distance of tumour edge to -

Distal margin (mm): 15mm

Proximal margin (mm): 19mm

Micro Report

Adenocarcinoma: Yes

Lauren classification: Mixed

Differentiation: Poor

Local invasion into: Tumour penetrates peritoneum without invasion of adjacent structures (T4)

Lymph node spread:

Total number of regional lymph nodes examined: 13

Number of lymph nodes involved: 9

Distant metastases: Unknown

Margins:

Tumour involvement of -

Proximal donut (Y/N): N/A

Distal donut (Y/N): N/A

Proximal margin Main specimen Y/N: Clear

Distal margin Main specimen Y/N: Clear

Cicumferential margin lower oesophagus N/A

Other Pathology:

Chronic gastritis Y/N: Yes

ACKNOWLEDGEMENT OF RECEIPT	
WARD SECRETARY	DOCTOR

[page 3 of 4]
Atrophy Y/N: Yes
Intestinal metaplasia Y/N: Yes
H.pylori Y/N: No
Other lesions Y/N: No

Comments:

This is a widely infiltrating poorly differentiated adenocarcinoma with evidence of widespread lymphovascular invasion. Within the background mucosa there is evidence of chronic inflammation and intestinal metaplasia indicating underlying chronic gastritis.

History of neoadjuvant therapy Y/N: No

Pathological Staging (TNM7): pT4a, pN1, pMx

Complete resection at all margins: Yes

Signature of Pathologist(s)

Dr

Dr

Page 3 of 3

ACKNOWLEDGEMENT OF RECEIPT		
WARD SECRETARY	DOCTOR	
Per TSS dx discrepancy form, TCGA tumor is intestinal carcinoma, tubular.		

[page 4 of 4]
TCGA Pathologic Diagnosis Discrepancy Form

V1.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	INTESTINAL ADENOCARCINOMA NOS	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	INTESTINAL ADENOCARCINOMA TUBULAR	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	Predominantly tubular on sample submitted	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director	_____	Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file 109b118b-d543-42e4-8881-75f1c990891c (TCGA-ZQ-A9CR.4C5A488B-9D28-4EC3-8E19-AE1D0C783909.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).